CCDI case PBBVDC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Oropharynx.
https://portal.gdc.cancer.gov/cases/7200cda3-cb90-49c0-a5fa-63b7d849f4e3

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Oropharynx, NOS; Age at diagnosis: 7.8 years (2,851 days).

Biospecimens (2 samples)
- Sample 0DJE3A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DJE3F: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
